Somatic mutation profile of tumor specimen 0DE3HH from CCDI case PBBLPZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain stem; Age at diagnosis: 16.8 years (6,133 days).
Specimen 0DE3HH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 943ea064-f2e3-42ba-8de6-2cfd93fa3c8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DE3GU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e26d1b84-9bf6-45b2-a18c-ceb130782747

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRA1 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 98/463 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs780636701, COSV66927472; called by muse, mutect2, varscan2
- MYH7B | c.5674G>A p.E1892K | Missense Mutation (SNP) | VAF 53/488 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1438801397; called by muse, mutect2, varscan2
- ZNF92 | c.481A>C p.N161H (on ENST00000328747 / NM_152626.4; = p.N92H on NM_007139.4) | Missense Mutation (SNP) | VAF 137/532 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV100165667; called by muse, mutect2, varscan2
- MYO18B | c.1580-1G>A p.X527_splice | Splice Site (SNP) | VAF 65/572 reads (11%) | called by muse, varscan2
- BCAN | c.2335C>T p.L779= | Silent (SNP) | VAF 184/1006 reads (18%) | called by muse, mutect2
- ZIC1 | c.*36A>G | 3'UTR (SNP) | VAF 17/427 reads (4%) | called by muse, mutect2
